Gene-level copy-number profile of tumor specimen C3N-00209-03 from CPTAC case C3N-00209, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 81.7 years (29,831 days).
Specimen C3N-00209-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 252b404e-6fd2-4c8d-93b5-38a2dd396f04.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00209-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/f01070a6-0a07-457f-b3c3-1c45694ba0cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 371; copy number 1: 17,093; copy number 2: 36,650; copy number 3: 4,569; copy number 4: 176; copy number 5: 43.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:171,773,652–172,691,540, 14 genes (within-gene range 0–1): AC011410.1, SMIM23, FBXW11, STK10, EFCAB9, UBTD2, AC024561.1, KLF3P1, SH3PXD2B, LINC01944, AC027309.3, NEURL1B, AC027309.2, MIR5003.
- chr5:177,707,981–177,803,344, 3 genes (within-gene range 0–1): FAM153A, AC140125.2, AC140125.1.
- chr5:177,836,434–177,837,646, 1 gene (within-gene range 0–1): OR1X5P.
- chr9:39,072,767–40,153,147, 30 genes (within-gene range 0–1): CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1, AL772307.1, RPL7AP49, AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:64,369,394–64,466,498, 5 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P.
- chr10:46,375,627–46,537,864, 5 genes (within-gene range 0–1): ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr17:45,506,741–45,588,379, 9 genes: LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1, AC091132.4, AC091132.5, RDM1P1, DND1P1, AC126544.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 43 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,188,682–46,316,776, 5 genes, copy number 5: POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH.
- chr1:119,414,931–120,100,779, 24 genes, copy number 5: HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1.
- chr20:362,835–610,398, 6 genes, copy number 5: TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15.
- chr20:1,516,759–1,657,779, 8 genes, copy number 5: AL049634.1, RNU6-917P, SIRPD, AL049634.2, SIRPB1, AL049634.3, SIRPG, SIRPG-AS1.

Autosomal genes at a single copy (total copy number 1): 14,541. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
